Somatic mutation profile of tumor specimen HCM-WCMC-1340-C54-01A (aliquot HCM-WCMC-1340-C54-01A-15D-A937-36) from HCMI case HCM-WCMC-1340-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage I; FIGO stage: Stage IIIA; Age at diagnosis: 64.0 years (23,370 days).
Specimen HCM-WCMC-1340-C54-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e45a68c-8c42-4c2d-b9df-f281c1d28a0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1340-C54-12A (Saliva), aliquot HCM-WCMC-1340-C54-12A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/569b3ea0-694c-4cf3-8553-98a15b08f125

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLXNB2 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV100834261; called by muse, mutect2
- BAG6 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.023); called by muse, mutect2
- LSP1 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- NAMPT | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRPSAP2 | c.889G>C p.A297P | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.221); called by muse, mutect2
- WNK2 | c.5318A>C p.Q1773P (on ENST00000297954 / NM_001282394.1; = p.Q1736P on NM_006648.3) | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); called by muse, mutect2
- CHRM2 | c.1155C>T p.V385= | Silent (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- OR8K1 | c.879G>A p.P293= | Silent (SNP) | VAF 22/553 reads (4%) | catalogued as rs545105332, COSV54403279; called by muse, mutect2
- PRR33 | c.639C>A p.T213= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as rs1263738692; called by muse, mutect2
- RAI1 | c.4167G>A p.Q1389= | Silent (SNP) | VAF 9/246 reads (4%) | catalogued as rs999677571, COSV55394274; called by muse, mutect2
